Gene-level copy-number profile of tumor specimen ALCH-B3ZZ-TTP1-A from ALCHEMIST case ALCH-B3ZZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Age at diagnosis: 67.7 years (24,725 days).
Specimen ALCH-B3ZZ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 442cc902-2c44-40ec-bc62-8471afc42986.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3ZZ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/3d559b63-9eab-4bc3-89f6-73a40434d297

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 23,281; copy number 2: 29,237; copy number 3: 5,365; copy number 4: 469; copy number 5: 396; copy number 6: 17; copy number 7: 84; copy number 8: 4; copy number 14: 4; copy number 24: 1.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:49,674,014–49,721,529, 4 genes (within-gene range 0–1): APEH, MST1, AC099668.1, RNF123.
- chr4:4,117,925–4,127,569, 2 genes: AC116562.1, OR7E103P.
- chr9:61,190,003–61,453,030, 7 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr9:130,892,707–130,945,520, 3 genes: QRFP, FIBCD1, AL161733.1.
- chr13:57,204,379–57,204,799, 1 gene: MTCO2P3.
- chr17:68,095,068–68,101,496, 2 genes: FBXO36P1, AC145343.1.
- chr19:58,012,589–58,025,926, 2 genes: VN2R19P, AC008969.2.
- chr20:25,284,915–25,285,588, 1 gene (within-gene range 0–2): AL121772.3.
- chr21:36,016,079–36,016,546, 1 gene: RPL23AP3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 373 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:14,143,342–16,192,709, 29 genes, copy number 5–8: TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, U8, LINC02149, MARK2P5, AC114964.2, AC114964.1, FBXL7, CTD-2350J17.1, MIR887, RNA5SP178, MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6.
- chr8:106,359,476–134,390,487, 318 genes, copy number 5 (broad region; genes not listed).
- chr9:114,334,156–115,744,330, 20 genes, copy number 5 (within-gene range 4–5): AKNA, AL138895.1, WHRN, AL138895.2, AL160275.2, ATP6V1G1, TMEM268, Y_RNA, TEX53, TEX48, AL160275.1, AL390240.1, TNFSF15, AL133412.1, DELEC1, TNFSF8, TNC, AL162425.1, AL355601.1, AL691420.1.
- chr11:1,947,278–1,984,522, 1 gene, copy number 24 (within-gene range 3–24): MRPL23.
- chr11:1,995,176–2,001,470, 4 genes, copy number 14: H19, AC051649.3, MIR675, AC051649.2.
- chr21:10,649,400–10,649,835, 1 gene, copy number 6: IGHV1OR21-1.

Autosomal genes at a single copy (total copy number 1): 21,367. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
